Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5497, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5497-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 7.2, surgery for deviated septum and sleep apnea, Botox injections for hyperhidrosis. The patient also has a history of biopsy on [REDACTED] his biopsy reveals unilateral poorly differentiated prostatic adenocarcinoma of the left thigh and.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

TCGA-EJ-5497

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN SIX LYMPH NODES (0/6).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN FOUR LYMPH NODES (0/4).

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES, AND BILATERAL DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7.
- B. CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT SIDES OF PROSTATE AND HAS A GREATEST NODULAR DIAMETER OF 2.0 CM IN ONE HISTOLOGIC SECTION.
- C. THE TUMOR INVOLVES APPROXIMATELY 10% OF THE EXAMINED PROSTATE VOLUME.
- D. CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRAPROSTATIC EXTENSION.
- E. BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA ARE FREE OF TUMOR.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- G. MULTIFOCAL PERINEURAL INVASION IS PRESENT.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS PRESENT.
- J. PATHOLOGIC TNM STAGE: pT2c N0 MX.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 7.2
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	25%
WEIGHT OF PROSTATE:	72.98gm
TUMOR SIZE:	Maximum dimension: 2.0 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	10
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 003dc9ef-da7e-4807-a20e-767d2e9d3707 (TCGA-EJ-5497.4C6AB617-53F7-4556-A1A0-B44DF4F67B6B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).